Somatic mutation profile of tumor specimen TCGA-VQ-A8PH-01A (aliquot TCGA-VQ-A8PH-01A-12D-A410-08) from TCGA case TCGA-VQ-A8PH, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 62.8 years (22,940 days).
Specimen TCGA-VQ-A8PH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4a0d27f6-b3c0-4510-a3c5-028e6bf4258a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-A8PH-10A (Blood Derived Normal), aliquot TCGA-VQ-A8PH-10A-01D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c8d6b307-696c-4a83-97e0-180b77f3d7e7

The open-access MAF lists 214 somatic variants for this specimen: 170 protein-altering or splice-affecting, 39 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 144, Silent 39, Nonsense Mutation 8, Frame Shift Del 6, In Frame Del 5, Splice Site 5, Intron 3, Nonstop Mutation 1, Splice Region 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DYRK1A | c.829G>C p.A277P | Missense Mutation (SNP) | VAF 53/83 reads (64%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as rs1064795422, COSV100117426; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.775G>T p.D259Y | Missense Mutation (SNP) | VAF 16/32 reads (50%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as rs1567548929, COSV52662086, COSV52675732, COSV52773165, COSV52962390; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AC013489.1 | c.958T>G p.F320V | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.182); catalogued as COSV99183826; called by muse, mutect2, varscan2
- ACOT7 | c.547C>T p.R183W (on ENST00000377855 / NM_181864.3; = p.R173W on NM_007274.4) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.779); catalogued as rs746248748, COSV64115084; called by muse, mutect2, varscan2
- ADAMTS2 | c.3617A>T p.E1206V | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99280920; called by muse, mutect2, varscan2
- ADAMTS5 | c.2360A>T p.N787I | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99537037; called by muse, mutect2, varscan2
- ADGRL2 | c.3895G>A p.D1299N (on ENST00000370717 / NM_001366005.1; = p.D1243N on NM_012302.4) | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.049); catalogued as rs751411562, COSV99587112; called by muse, mutect2, varscan2
- ADGRV1 | c.1616T>A p.L539* | Nonsense Mutation (SNP) | VAF 12/22 reads (55%) | catalogued as COSV101315503, COSV67985394; called by muse, mutect2, varscan2
- AGBL5 | c.896G>A p.R299Q | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as rs754128307; called by muse, mutect2, varscan2
- AHR | c.241A>T p.S81C | Missense Mutation (SNP) | VAF 34/184 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); catalogued as COSV99619264; called by muse, mutect2, varscan2
- AMOTL2 | c.706A>T p.S236C | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV99997990; called by muse, mutect2, varscan2
- AMPH | c.928A>T p.T310S | Missense Mutation (SNP) | VAF 48/147 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100340915, COSV57759541; called by muse, mutect2, varscan2
- ARPP21 | c.714A>C p.L238F | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.649); catalogued as COSV99490987; called by muse, mutect2, varscan2
- ASPM | c.9884C>G p.A3295G | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs375308966, COSV99659545; called by muse, mutect2, varscan2
- B4GALNT1 | c.601G>C p.E201Q | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.893); catalogued as rs546888005, COSV100246941, COSV57543338; called by muse, mutect2, varscan2
- BMX | c.1160G>A p.R387Q | Missense Mutation (SNP) | VAF 41/55 reads (75%) | SIFT deleterious (0.01); PolyPhen benign (0.309); catalogued as COSV100564296; called by muse, mutect2, varscan2
- BTAF1 | c.4892G>A p.G1631D | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs1439369555; called by muse, mutect2
- CASP14 | c.634C>T p.R212W | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as rs200139686, COSV55665640; called by muse, mutect2
- CBFB | c.79-2A>T p.X27_splice | Splice Site (SNP) | VAF 13/26 reads (50%) | catalogued as COSV51999338, COSV99325468; called by muse, mutect2, varscan2
- CD82 | c.385A>T p.N129Y | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV99907378; called by muse, mutect2, varscan2
- CENPH | c.145C>G p.Q49E | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as COSV99295474; called by muse, mutect2, varscan2
- CLEC14A | c.986A>T p.E329V | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.714); catalogued as COSV100643492; called by muse, mutect2, varscan2
- CLEC14A | c.985G>T p.E329* | Nonsense Mutation (SNP) | VAF 34/83 reads (41%) | catalogued as COSV100643493; called by muse, mutect2, varscan2
- COG1 | c.38T>C p.L13P | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.011); catalogued as COSV100245128; called by muse, mutect2, varscan2
- COL11A1 | c.4554+2T>A p.X1518_splice | Splice Site (SNP) | VAF 5/43 reads (12%) | catalogued as COSV100615157; called by muse, mutect2, varscan2
- COL11A1 | c.223A>T p.R75* | Nonsense Mutation (SNP) | VAF 46/106 reads (43%) | catalogued as COSV100615159, COSV62185432; called by muse, mutect2, varscan2
- COL15A1 | c.2275C>G p.P759A | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as COSV100897418; called by muse, mutect2, varscan2
- COPS2 | c.297T>G p.I99M | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.245); catalogued as COSV100157105; called by muse, mutect2, varscan2
- CTTNBP2NL | c.1919A>T p.*640Lext*9 | Nonstop Mutation (SNP) | VAF 16/87 reads (18%) | catalogued as COSV99599767; called by muse, mutect2, varscan2
- CUL9 | c.5563C>A p.L1855M | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); catalogued as COSV99334784; called by muse, mutect2, varscan2
- CXCR4 | c.1052C>A p.S351Y | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV99602495; called by muse, mutect2
- CYP11B2 | c.733T>C p.S245P | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as rs779948954, COSV100010652; called by muse, mutect2, varscan2
- CYP27A1 | c.207_209del p.F70del | In Frame Del (DEL) | VAF 12/36 reads (33%) | catalogued as rs774193477; called by pindel, varscan2
- DISC1 | c.286C>T p.R96W | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.409); catalogued as rs1417808440, COSV99697175; called by muse, mutect2, varscan2
- DNAH11 | c.986T>C p.L329P | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100177152; called by mutect2, varscan2
- DNAJC24 | c.395del p.S132Tfs*2 | Frame Shift Del (DEL) | VAF 8/39 reads (21%) | catalogued as rs1564960308; called by mutect2, pindel, varscan2
- DOCK4 | c.5717A>T p.Y1906F | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.931); catalogued as COSV101447780, COSV101447933; called by muse, mutect2, varscan2
- DSG2 | c.2257G>A p.A753T | Missense Mutation (SNP) | VAF 43/71 reads (61%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as COSV99852753; called by muse, mutect2, varscan2
- EIF3E | c.1306A>T p.N436Y | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.66); PolyPhen benign (0.013); catalogued as COSV99622804; called by muse, mutect2, varscan2
- EMC1 | c.1745C>G p.P582R | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100916412; called by muse, mutect2, varscan2
- EML3 | c.1529C>A p.A510D | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.239); catalogued as COSV99604009; called by muse, mutect2
- ERBB2 | c.79A>T p.T27S | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.71); PolyPhen benign (0.095); catalogued as COSV99506711; called by muse, mutect2, varscan2
- ERLEC1 | c.994G>A p.D332N | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.157); catalogued as rs1435791408, COSV99482839; called by muse, mutect2, varscan2
- FEN1 | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as rs762018999, COSV99952775; called by muse, mutect2, varscan2
- GABRA6 | c.278A>T p.K93M | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.513); catalogued as rs1464784957, COSV50882157, COSV99194066; called by muse, mutect2, varscan2
- GIGYF2 | c.2312G>A p.R771Q | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.105); catalogued as rs751897275, COSV101003883; called by muse, mutect2, varscan2
- GRAMD1C | c.1931T>A p.L644H | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100362037; called by muse, mutect2, varscan2
- GRM3 | c.878C>A p.A293D | Missense Mutation (SNP) | VAF 48/90 reads (53%) | SIFT tolerated (0.64); PolyPhen benign (0.08); catalogued as COSV100862095, COSV64466532, COSV64481485; called by muse, mutect2, varscan2
- GTF3C1 | c.535T>C p.C179R | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100648971; called by muse, mutect2, varscan2
- GXYLT1 | c.988+1G>A p.X330_splice | Splice Site (SNP) | VAF 27/107 reads (25%) | catalogued as COSV99787817; called by muse, mutect2, varscan2
- HEATR1 | c.1573C>T p.R525* | Nonsense Mutation (SNP) | VAF 10/59 reads (17%) | catalogued as COSV63981080; called by muse, mutect2, varscan2
- HERC2 | c.5174G>C p.R1725P | Missense Mutation (SNP) | VAF 74/252 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.774); catalogued as COSV55328815, COSV99870998; called by muse, mutect2, varscan2
- HIPK3 | c.1039T>G p.S347A | Missense Mutation (SNP) | VAF 67/155 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100305401; called by muse, mutect2, varscan2
- HMCN1 | c.12006C>A p.N4002K | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.612); catalogued as rs758672862, COSV54893270, COSV99624247; called by muse, mutect2, varscan2
- IRF4 | c.622C>T p.P208S | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV101110762; called by muse, mutect2, varscan2
- ITIH2 | c.28T>A p.C10S | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as COSV100623159; called by muse, mutect2, varscan2
- KCNJ9 | c.489G>C p.Q163H | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100927701; called by muse, mutect2, varscan2
- KCNK9 | c.316G>C p.G106R | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100270367; called by muse, mutect2, varscan2
- KCNMA1 | c.1502A>T p.E501V | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99695024; called by muse, mutect2, varscan2
- KCNMA1 | c.1400A>T p.Q467L | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.687); catalogued as rs754219838, COSV99695030; called by muse, mutect2, varscan2
- KCTD3 | c.578A>T p.H193L | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.314); catalogued as COSV99378826; called by muse, mutect2
- KCTD3 | c.1129C>A p.P377T | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99378830; called by muse, mutect2, varscan2
- KIF7 | c.2375C>T p.A792V | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as rs375985448, COSV101067258; called by muse, mutect2, varscan2
- KNDC1 | c.557G>A p.R186H | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs763861007, COSV100463361; called by muse, mutect2, varscan2
- KRT75 | c.1649C>A p.T550K | Missense Mutation (SNP) | VAF 23/162 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV52873636, COSV99359174; called by muse, mutect2, varscan2
- LAMA1 | c.1805G>T p.S602I | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.3); PolyPhen benign (0.257); catalogued as COSV101055032; called by muse, mutect2, varscan2
- LAMA3 | c.2303A>G p.Q768R | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV100555536; called by mutect2, varscan2
- LEPR | c.2225A>T p.Q742L | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as rs1246238288, COSV100756294; called by muse, mutect2, varscan2
- LIMS1 | c.777A>G p.I259M | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100185470; called by muse, mutect2, varscan2
- LMBRD2 | c.1429A>T p.S477C | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99682586; called by muse, mutect2, varscan2
- LMTK3 | c.4261C>T p.L1421F | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.946); catalogued as COSV99539978; called by muse, mutect2, varscan2
- LRRC3 | c.300C>G p.I100M | Missense Mutation (SNP) | VAF 34/57 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs140245260, COSV99381696; called by muse, mutect2, varscan2
- MAG | c.1017G>C p.E339D | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV100727606; called by muse, mutect2, varscan2
- MALT1 | c.458A>T p.H153L | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as COSV100618586; called by muse, mutect2, varscan2
- MANEA | c.457A>T p.S153C | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV100721446; called by muse, mutect2, varscan2
- MAP4K1 | c.1234G>A p.G412R | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.997); catalogued as rs1197358011, COSV67711324; called by muse, mutect2, varscan2
- MAST4 | c.5215C>T p.R1739* (on ENST00000403625 / NM_001164664.2; = p.R1550* on NM_015183.3) | Nonsense Mutation (SNP) | VAF 7/22 reads (32%) | catalogued as COSV99842871; called by muse, mutect2, varscan2
- MDC1 | c.3137C>T p.P1046L | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1471495175, COSV100902569; called by muse, mutect2, varscan2
- MORN1 | c.1043G>A p.G348E | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as COSV101047772; called by muse, mutect2, varscan2
- MPDZ | c.854T>A p.L285Q | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100060273, COSV100060768; called by muse, mutect2, varscan2
- MTMR8 | c.1084A>G p.T362A | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.647); catalogued as rs1165368332, COSV100878273; called by muse, mutect2, varscan2
- MUSK | c.2486T>A p.V829E | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (0.14); PolyPhen benign (0.034); catalogued as COSV99503674; called by muse, mutect2, varscan2
- MYO9A | c.6020A>G p.Y2007C | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs760390220, COSV100612645; called by muse, mutect2, varscan2
- NAA20 | c.505C>T p.P169S | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV100131478; called by muse, mutect2, varscan2
- NAV3 | c.3263G>A p.S1088N | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99887043; called by muse, mutect2
- NCAM2 | c.212A>T p.K71M | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.853); catalogued as COSV99521282; called by muse, mutect2, varscan2
- NIPBL | c.6083A>C p.Q2028P | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99238836; called by muse, mutect2, varscan2
- NPAP1 | c.539T>A p.L180H | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.791); catalogued as COSV61510142, COSV61512194; called by muse, mutect2, varscan2
- NR2F2 | c.670G>C p.V224L | Missense Mutation (SNP) | VAF 18/312 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.61); catalogued as COSV101240898, COSV101240919; called by muse, mutect2
- NRG3 | c.1540G>A p.E514K | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs564020344, COSV64551383; called by muse, mutect2, varscan2
- NUP98 | c.1999A>T p.I667F | Missense Mutation (SNP) | VAF 25/36 reads (69%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV100261505; called by muse, mutect2, varscan2
- OR10A4 | c.199T>A p.L67M | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65841945, COSV65842200; called by muse, mutect2, varscan2
- OR4D9 | c.404T>A p.I135N | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV100259706; called by muse, mutect2, varscan2
- OR51G1 | c.418C>T p.P140S | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as rs777287911, COSV100429138; called by muse, mutect2, varscan2
- OR52A5 | c.523A>T p.T175S | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.063); catalogued as COSV100263291; called by muse, mutect2, varscan2
- PCDH15 | c.329A>C p.N110T | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT tolerated (0.05); PolyPhen benign (0.165); catalogued as COSV100215363; called by muse, mutect2, varscan2
- PCDHA11 | c.1561C>G p.P521A | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV100247636; called by muse, mutect2, varscan2
- PCDHA11 | c.1747T>A p.S583T | Missense Mutation (SNP) | VAF 51/119 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.12); catalogued as COSV100247638; called by muse, mutect2, varscan2
- PCDHB2 | c.1257C>A p.Y419* | Nonsense Mutation (SNP) | VAF 11/65 reads (17%) | catalogued as COSV99164060; called by muse, mutect2, varscan2
- PCDHGB7 | c.446G>A p.G149E | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV53992398; called by muse, mutect2, varscan2
- PHETA1 | c.14A>T p.E5V | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100825301; called by muse, mutect2, varscan2
- PNMA8B | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 34/53 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as rs1162974031, COSV100885292; called by muse, mutect2, varscan2
- PRICKLE1 | c.1231C>T p.H411Y | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.937); catalogued as COSV100566095; called by muse, mutect2, varscan2
- PRR5L | c.668G>T p.G223V | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV100286823; called by muse, mutect2, varscan2
- PSAP | c.248A>T p.E83V | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV101206422; called by muse, mutect2, varscan2
- PSME4 | c.4041T>C p.G1347= | Splice Region (SNP) | VAF 22/38 reads (58%) | catalogued as COSV101122229; called by muse, mutect2, varscan2
- PTCHD3 | c.1469T>A p.I490N | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101438823; called by muse, mutect2, varscan2
- PTPRD | c.2656C>G p.H886D | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.643); catalogued as COSV100643369; called by muse, mutect2, varscan2
- RHBDF1 | c.1049C>T p.P350L | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs759878923, COSV51955371, COSV51956086; called by muse, mutect2, varscan2
- RHCE | c.908T>A p.L303Q | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as CM099531, COSV99603716; called by muse, mutect2, varscan2
- RMND1 | c.82C>G p.L28V | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.021); catalogued as COSV100323519; called by muse, mutect2, varscan2
- RNF43 | c.118A>T p.R40* | Nonsense Mutation (SNP) | VAF 27/65 reads (42%) | catalogued as COSV100089802; called by muse, mutect2, varscan2
- RYR1 | c.9061C>A p.P3021T | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.941); catalogued as COSV100614484; called by muse, mutect2, varscan2
- SCG2 | c.650A>T p.E217V | Missense Mutation (SNP) | VAF 31/176 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.42); catalogued as COSV100544592; called by muse, mutect2, varscan2
- SEC24A | c.1047A>T p.R349S | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.434); catalogued as COSV100524320; called by muse, mutect2, varscan2
- SGK1 | c.1106C>G p.T369S | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV99397733; called by muse, mutect2, varscan2
- SGK3 | c.1393T>A p.S465T | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.088); catalogued as COSV100616580; called by muse, mutect2, varscan2
- SHOC1 | c.457T>G p.C153G | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.014); catalogued as COSV100597261; called by muse, mutect2, varscan2
- SIK3 | c.1387A>T p.T463S (on ENST00000445177 / NM_001366686.2; = p.T469S on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV99407247; called by muse, mutect2, varscan2
- SLC39A14 | c.965G>A p.C322Y | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99249568; called by muse, mutect2, varscan2
- SMAD7 | c.809A>T p.K270M | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV100052730; called by muse, mutect2, varscan2
- SMC4 | c.1465A>T p.S489C | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.025); catalogued as COSV100643933; called by muse, mutect2, varscan2
- SMG7 | c.2806G>A p.G936R | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.623); catalogued as rs556853158, COSV100750077; called by muse, mutect2, varscan2
- SNPH | c.643T>A p.Y215N | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100377947; called by muse, mutect2
- SPATA1 | c.222A>T p.K74N | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs754706903, COSV99759620; called by muse, mutect2, varscan2
- SPATS2L | c.1181A>T p.H394L | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.921); catalogued as rs1228688147, COSV100660472, COSV62348600; called by muse, mutect2, varscan2
- SPP1 | c.553A>G p.T185A (on ENST00000395080 / NM_001040058.2; = p.T171A on NM_000582.2) | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.053); catalogued as COSV99420846; called by muse, mutect2, varscan2
- SSTR3 | c.270C>G p.D90E | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100142513, COSV100142517; called by muse, mutect2, varscan2
- TCN1 | c.267T>A p.D89E | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as COSV99953084; called by muse, mutect2, varscan2
- THSD7A | c.1525T>A p.C509S | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101448545; called by muse, mutect2, varscan2
- TICAM1 | c.920G>T p.G307V | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV99940987; called by muse, mutect2, varscan2
- TLR6 | c.2240A>T p.K747M | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV101126234; called by muse, mutect2, varscan2
- TMEM26 | c.566T>C p.L189P | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99515444; called by muse, mutect2, varscan2
- TMEM74 | c.44T>A p.L15H | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.518); catalogued as COSV99865402; called by muse, mutect2, varscan2
- TPX2 | c.1086G>C p.K362N | Missense Mutation (SNP) | VAF 267/350 reads (76%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); catalogued as COSV100301517; called by muse, mutect2, varscan2
- TRARG1 | c.282T>A p.Y94* | Nonsense Mutation (SNP) | VAF 21/53 reads (40%) | catalogued as COSV100416734; called by muse, mutect2, varscan2
- TRMT6 | c.377A>T p.Q126L | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV99177512; called by muse, mutect2, varscan2
- TRO | c.3289C>G p.P1097A | Missense Mutation (SNP) | VAF 25/37 reads (68%) | SIFT tolerated (0.6); PolyPhen benign (0.046); catalogued as COSV51505835, COSV99435756; called by muse, mutect2, varscan2
- TRPM1 | c.1850T>A p.V617E | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV99855353; called by muse, mutect2, varscan2
- TRRAP | c.3067A>C p.T1023P | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV100721985; called by muse, mutect2, varscan2
- TSPAN31 | c.193G>C p.V65L | Missense Mutation (SNP) | VAF 9/154 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.077); catalogued as rs1565803219, COSV99222224; called by muse, mutect2
- TTF2 | c.2398A>T p.N800Y | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101037266; called by muse, mutect2, varscan2
- TTLL10 | c.898T>A p.F300I (on ENST00000379289 / NM_001130045.2; = p.F227I on NM_153254.3) | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101016428; called by muse, mutect2
- TTN | c.80987G>C p.S26996T (on ENST00000591111; = p.S19572T on NM_003319.4) | Missense Mutation (SNP) | VAF 16/67 reads (24%) | PolyPhen probably damaging (0.991); catalogued as COSV100594496; called by muse, mutect2, varscan2
- TTN | c.75816G>C p.W25272C (on ENST00000591111; = p.W17848C on NM_003319.4) | Missense Mutation (SNP) | VAF 24/114 reads (21%) | PolyPhen benign (0.04); catalogued as COSV100594497; called by muse, mutect2, varscan2
- UBC | c.86A>T p.K29M | Missense Mutation (SNP) | VAF 90/259 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.988); catalogued as COSV100298793; called by muse, mutect2, varscan2
- USP15 | c.2830C>G p.L944V (on ENST00000280377 / NM_001351159.2; = p.L915V on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/145 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0.095); catalogued as COSV99738554; called by muse, mutect2, varscan2
- USP3 | c.841A>T p.N281Y | Missense Mutation (SNP) | VAF 49/134 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.206); catalogued as COSV99165633; called by muse, mutect2, varscan2
- UTRN | c.9515T>A p.M3172K | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV100837806; called by muse, mutect2, varscan2
- VGF | c.632G>A p.G211E | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as COSV99972836; called by muse, mutect2, varscan2
- VRK2 | c.53G>A p.G18D | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.674); catalogued as COSV100417562; called by muse, mutect2, varscan2
- WDR49 | c.652-2A>C p.X218_splice (on ENST00000308378 / NM_001366158.1; = p.X559_splice on NM_001348951.2 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 17/55 reads (31%) | catalogued as COSV100391713; called by muse, mutect2, varscan2
- WDR59 | c.1684G>A p.A562T | Missense Mutation (SNP) | VAF 44/74 reads (59%) | SIFT tolerated (0.71); PolyPhen benign (0.058); catalogued as COSV100048910; called by muse, varscan2
- ZDHHC12 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs371352520, COSV52577925; called by muse, mutect2, varscan2
- ZNF213 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs749303187, COSV67727667; called by muse, mutect2, varscan2
- ZNF214 | c.148A>G p.K50E | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.87); PolyPhen benign (0.007); catalogued as COSV99547190; called by muse, mutect2, varscan2
- ZNF343 | c.643C>G p.P215A | Missense Mutation (SNP) | VAF 69/108 reads (64%) | SIFT tolerated (0.44); PolyPhen benign (0.153); catalogued as COSV53856296; called by muse, mutect2, varscan2
- ZNF396 | c.857A>T p.K286M | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100108464; called by muse, mutect2
- ZNF718 | c.371A>T p.Q124L | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.747); catalogued as COSV101210229; called by muse, mutect2, varscan2
- ZNF777 | c.1235A>G p.D412G | Missense Mutation (SNP) | VAF 35/55 reads (64%) | SIFT tolerated (0.24); PolyPhen benign (0.133); catalogued as COSV99924990; called by muse, mutect2, varscan2
- ADAM15 | c.1461_1462del p.C487* | Frame Shift Del (DEL) | VAF 10/74 reads (14%) | called by pindel, varscan2
- CNOT2 | c.171+2dup p.X57_splice | Splice Site (INS) | VAF 20/84 reads (24%) | called by mutect2, pindel, varscan2
- CXCR4 | c.866_880del p.A289_H294delinsD | In Frame Del (DEL) | VAF 14/111 reads (13%) | called by mutect2, pindel*
- DOCK2 | c.2608del p.E870Sfs*50 | Frame Shift Del (DEL) | VAF 26/59 reads (44%) | called by mutect2, pindel, varscan2
- HIVEP3 | c.2370_2372del p.R791del | In Frame Del (DEL) | VAF 10/47 reads (21%) | called by pindel, varscan2
- KLHL28 | c.388del p.S130Afs*61 | Frame Shift Del (DEL) | VAF 32/79 reads (41%) | called by mutect2, pindel, varscan2
- MDN1 | c.12892del p.Q4298Rfs*17 | Frame Shift Del (DEL) | VAF 11/30 reads (37%) | called by mutect2, pindel, varscan2
- NLRP8 | c.2915_2917del p.A972_M973delinsV | In Frame Del (DEL) | VAF 8/98 reads (8%) | called by mutect2, pindel
- SPAG4 | c.1266_1304del p.V423_G435del | In Frame Del (DEL) | VAF 12/50 reads (24%) | called by mutect2, pindel
- ZNF229 | c.427_434del p.W143Sfs*9 | Frame Shift Del (DEL) | VAF 49/231 reads (21%) | called by mutect2, pindel, varscan2
- ACTC1 | c.168A>T p.V56= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV51758843, COSV99291596; called by muse, mutect2, varscan2
- ACTL8 | c.186C>G p.T62= | Silent (SNP) | VAF 39/82 reads (48%) | catalogued as COSV100958500; called by muse, mutect2, varscan2
- C9orf85 | c.189A>T p.P63= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV100594959; called by muse, mutect2
- CHD4 | c.2145C>T p.P715= (on ENST00000357008 / NM_001363606.2; = p.P728= on NM_001273.5) | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as rs368003608; called by muse, mutect2, varscan2
- COL16A1 | c.189T>A p.S63= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV99593573; called by muse, mutect2, varscan2
- DOCK1 | c.2046C>T p.I682= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as rs763133308, COSV99726843; called by muse, mutect2, varscan2
- EGFL6 | c.930G>A p.K310= | Silent (SNP) | VAF 48/66 reads (73%) | catalogued as rs373733897, COSV100789844; called by muse, mutect2, varscan2
- ELAC2 | c.1035A>T p.P345= | Silent (SNP) | VAF 33/67 reads (49%) | catalogued as COSV100568346; called by muse, mutect2, varscan2
- FAM204A | c.18A>T p.L6= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as COSV100977353; called by muse, mutect2, varscan2
- GJA8 | c.327C>T p.R109= | Silent (SNP) | VAF 23/78 reads (29%) | catalogued as COSV53788847; called by muse, mutect2, varscan2
- GRIN2A | c.4089C>T p.S1363= | Silent (SNP) | VAF 21/44 reads (48%) | catalogued as rs774385825, COSV58029885, COSV58031261; called by muse, mutect2, varscan2
- HERC2 | c.8871A>T p.I2957= | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as COSV99870994; called by muse, mutect2, varscan2
- HLX | c.1110T>A p.S370= | Silent (SNP) | VAF 3/21 reads (14%) | called by muse, mutect2
- KCNU1 | c.3168T>C p.Y1056= | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as COSV101298905; called by muse, mutect2, varscan2
- KLHDC1 | c.411A>T p.I137= | Silent (SNP) | VAF 26/44 reads (59%) | catalogued as COSV100833458; called by muse, mutect2, varscan2
- L3MBTL3 | c.1155C>T p.P385= | Silent (SNP) | VAF 25/147 reads (17%) | catalogued as COSV100695730; called by muse, mutect2, varscan2
- LAMA4 | c.3867T>A p.G1289= (on ENST00000230538 / NM_001105206.3; = p.G1282= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as COSV100037628; called by muse, mutect2, varscan2
- METTL2B | c.678A>T p.S226= | Silent (SNP) | VAF 52/97 reads (54%) | catalogued as COSV99299643; called by muse, mutect2, varscan2
- MIOS | c.1155T>C p.S385= | Silent (SNP) | VAF 36/96 reads (38%) | catalogued as COSV100402562; called by muse, mutect2, varscan2
- MMRN1 | c.2967G>A p.S989= | Silent (SNP) | VAF 29/56 reads (52%) | catalogued as rs762745325, COSV53333481; called by muse, mutect2, varscan2
- NAALADL2 | c.276A>T p.S92= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as COSV101435741; called by muse, mutect2, varscan2
- OPLAH | c.1602C>G p.P534= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs1554759405, COSV101470724; called by muse, mutect2, varscan2
- OPRK1 | c.462G>C p.V154= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as COSV55574033, COSV99653717; called by muse, mutect2, varscan2
- OR4L1 | c.495C>T p.N165= | Silent (SNP) | VAF 39/100 reads (39%) | catalogued as rs772790167, COSV100235557; called by muse, mutect2, varscan2
- PLEC | c.13345C>T p.L4449= (on ENST00000322810 / NM_201380.4; = p.L4339= on NM_000445.5) | Silent (SNP) | VAF 37/109 reads (34%) | catalogued as COSV100510705; called by muse, mutect2, varscan2
- PLEKHG5 | c.1779C>T p.D593= (on ENST00000400915 / NM_001042663.3; = p.D556= on NM_020631.6) | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as COSV100556103; called by muse, mutect2, varscan2
- PTCHD3 | c.2142G>A p.E714= | Silent (SNP) | VAF 22/50 reads (44%) | catalogued as COSV101438822; called by muse, mutect2, varscan2
- PTPRD | c.2655C>A p.I885= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as rs754293267, COSV100643370, COSV61982646; called by muse, mutect2, varscan2
- RAMP2 | c.489T>A p.L163= | Silent (SNP) | VAF 28/47 reads (60%) | catalogued as COSV99519681; called by muse, mutect2, varscan2
- RFX6 | c.1107T>C p.T369= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as COSV60584075; called by muse, mutect2, varscan2
- RTL9 | c.3636A>C p.S1212= | Silent (SNP) | VAF 29/55 reads (53%) | catalogued as COSV101511622; called by muse, mutect2, varscan2
- STK11IP | c.3105C>G p.L1035= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV99822229; called by muse, mutect2, varscan2
- TET1 | c.474T>G p.V158= | Silent (SNP) | VAF 18/83 reads (22%) | catalogued as COSV101017611; called by muse, mutect2
- TFPI2 | c.510T>C p.N170= | Silent (SNP) | VAF 27/88 reads (31%) | catalogued as COSV99746583; called by muse, mutect2, varscan2
- TMEM248 | c.378C>T p.F126= | Silent (SNP) | VAF 53/94 reads (56%) | catalogued as rs186391366; called by muse, mutect2, varscan2
- TOM1L1 | c.1119A>T p.T373= | Silent (SNP) | VAF 18/33 reads (55%) | catalogued as COSV100779137; called by muse, mutect2, varscan2
- TRPC6 | c.2544C>T p.F848= | Silent (SNP) | VAF 19/37 reads (51%) | catalogued as rs61890853, COSV100723463; called by muse, mutect2, varscan2
- VWA3A | c.2832G>A p.L944= | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as COSV100240613, COSV55394861; called by muse, mutect2, varscan2
- ZNF396 | c.855A>C p.A285= | Silent (SNP) | VAF 17/98 reads (17%) | catalogued as COSV100108466; called by muse, mutect2
- AP000769.5 | chr11:65498786 A>T | 5'Flank (SNP) | VAF 20/189 reads (11%) | called by muse, mutect2, varscan2
- EIF6 | c.107+35del | Intron (DEL) | VAF 164/246 reads (67%) | called by mutect2, pindel*, varscan2
- NACA | c.71-2936A>T | Intron (SNP) | VAF 13/73 reads (18%) | catalogued as rs780761309, COSV100771074; called by muse, mutect2, varscan2
- RNF217-AS1 | n.3134A>T | RNA (SNP) | VAF 6/17 reads (35%) | called by muse, mutect2, varscan2
- RORA | c.197-26392T>C | Intron (SNP) | VAF 9/31 reads (29%) | catalogued as COSV99832165; called by muse, mutect2, varscan2
